Surgical pathology report (de-identified scan), TCGA case TCGA-AF-3911, project TCGA-READ (Rectum Adenocarcinoma), tissue source site Christiana Healthcare, specimen TCGA-AF-3911-01A (Primary Tumor).

[page 1 of 3]
SPECIMEN

- A. Umbilical hernia sac
- B. Sigmoid and upper rectum
- C. Appendix

CLINICAL NOTES

PRE-OP DIAGNOSIS: Carcinoma of upper rectum.

GROSS DESCRIPTION

A. Received in formalin labeled "umbilical hernia sac" is a 4 x 3 x 1.5 cm yellow fatty tissue fragment, partially covered with pink-tan fibromembranous tissue. No discrete gross lesions are identified on sectioning. Representative sections of the specimen are submitted in two cassettes. RS-2. [REDACTED]

B. Received fresh, subsequently fixed in formalin labeled "sigmoid and upper rectum" is a 25 cm. long portion of colon. The specimen is partially covered with pink-tan smooth glistening serosa and yellow lobular fat. The retroperitoneal reflexion is located 5.5 cm. from the distal margin which is open. The proximal margin is stapled. The specimen shows pink-tan smooth glistening mucosa with a circumferential lesion. This lesion is located 2.7 cm. from the distal margin and the lesion is 5.5 x 4.5

x 0.7 cm. The cut surface of the tumor shows invasion into the muscularis propria, coming within 2.0 cm. of the radial margin. A sample is taken for tissue procurement. Upon further examination of sectioning, the lesion appears to be 0.7 cm. from becoming circumferential. Also located near the proximal end is a 0.5 cm. polyp which is located 1.5 cm. from the proximal end. The remainder of the mucosa was pink-tan smooth glistening with an average circumference of 4.5 cm. showing slightly dilated flattened folds. Lymph nodes are grossly identified in the fat. Representative sections of the specimen are submitted as follows: Block 1 - proximal margin with polyp; block 2 - representative luminal margin

GROSS DESCRIPTION

distal, block 3-5 - representative section of tumor including tumor to normal, tumor to deep; block 6 - representative radial margin, tumor to radial margin; block 7-11 - possible lymph nodes; block 12 - one possible lymph node bisected. RS-12. [REDACTED]

C. Received in formalin labeled "appendix" is a 4.2 x 0.5 cm. appendix which is partially covered yellow lobular fat and pink tan smooth glistening serosa. The specimen is sectioned to

[page 2 of 3]
show an intact wall with an average thickness of 0.3 cm. The specimen is sectioned and entirely submitted in one cassette with the proximal end inked. AS-1.

MICROSCOPIC DESCRIPTION

A, C. Microscopic examination performed.

B. Within the rectum there is an infiltrating moderately to poorly differentiated adenocarcinoma. Tumor extends through the bowel wall into pericolic fat. Please see the template below.

Histologic type: Adenocarcinoma.

Histologic grade: Moderately to poorly differentiated.

Primary tumor (pT): pT3

Proximal margin: Negative for tumor.

Distal margin: Negative for tumor.

Circumferential (radial) margin: Negative for tumor.

Distance of tumor from closest margin: The tumor is present to within 2.7 cm. of the distal margin.

Vascular invasion: Not detected.

Regional lymph nodes (pN): Metastatic disease is present to 9 of

18

regional lymph nodes, pN2.

Non-lymph node pericolic tumor: Two sites of non-lymph node

MICROSCOPIC DESCRIPTION

pericolic tumor present.

Distant metastasis (pM): Cannot be assessed.

Other findings: An adenomatous polyp is present near the proximal margin.

2x2, 5

[page 3 of 3]
DIAGNOSIS

- A. Umbilical hernia sac, herniorrhaphy - Adipose and fibromembranous tissue consistent with origin from hernia sac, negative for tumor.
- B. Sigmoid and upper rectum, segmental resection - Infiltrating adenocarcinoma of upper rectum, moderately to poorly differentiated, pT3. Metastatic disease to 9 of 18 regional lymph nodes (9/18); pericolic soft tissue tumor also present.
Adenomatous polyp.
- C. Appendix, appendectomy - Appendix, no significant pathology.
-

Source: NCI Genomic Data Commons file 221a5f38-b83c-42da-8c33-c9fa945b72e8 (TCGA-AF-3911.47E1E5EB-ACA0-4C2C-B5B0-4C80B49B22AF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).